Gene-level copy-number profile of tumor specimen CDDP-ACM1-TTP1-A from CDDP_EAGLE case CDDP-ACM1, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: female; Vital status: Alive; Primary diagnosis: Acinar cell carcinoma; Tissue or organ of origin: Lower lobe, lung; AJCC pathologic stage: Stage IB; Age at diagnosis: 70 years.
Specimen CDDP-ACM1-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file e84d22cb-8939-48c9-8f81-8b51a8b6feb7.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACM1-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,227 have no estimate.
https://portal.gdc.cancer.gov/files/7fd6f752-b080-4500-9ec8-8a668044e221

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 131; copy number 1: 15,347; copy number 2: 41,218; copy number 3: 1,543; copy number 4: 17; copy number 5: 45; copy number 6: 95.

Homozygous deletions (total copy number 0; autosomes only): 131 genes in 12 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:72,301,472–72,301,829, 1 gene: RPL31P12.
- chr2:90,359,809–91,580,863, 4 genes: AC233263.1, AC233263.7, AC233266.1, AC233266.2.
- chr5:135,802,985–135,803,075, 1 gene: MIR5692C1.
- chr6:25,983,812–26,546,933, 57 genes (within-gene range 0–1): U91328.2, U91328.1, U91328.3, H3P26, H1-1, H3C1, H4C1, H4C2, H3C2, H2AC4, H2BC3, H2AC5P, H3C3, H1-2, HFE, H4C3, H1-6, H2BC4, H2AC6, H1-4, H2BC5, AL353759.1, LARP1P1, H2BC6, H4C4, H1-12P, AL031777.2, H3C4, H2AC7, H2BC7, AL031777.1, H4C5, H2BC8, H2AC8, H3C5P, H3C6, H2AC9P, H1-3, H4C6, H4C7, H3C7, H2BC9, H3C8, H2AC10P, H2BC10, H4C8, H3C9P, BTN3A2, BTN2A2, BTN3A1, BTN2A3P, BTN3A3, BTN2A1, BTN1A1, RNU6-502P, HCG11, HMGN4.
- chr9:121,178,133–121,223,014, 2 genes (within-gene range 0–1): RAB14, RN7SL181P.
- chr14:18,333,726–19,384,587, 49 genes: CR383658.1, RNU6-458P, CR383658.2, BNIP3P6, CR383656.10, CR383656.7, CR383656.13, CR383656.9, OR11H12, CR383656.6, ARHGAP42P5, LINC02297, CR383656.5, CR383656.1, CR383656.12, CR383656.8, CR383656.11, CR383656.3, RPL22P20, CR383656.4, CR383656.2, NF1P10, NEK2P1, NF1P7, MED15P1, AL929601.1, AL929601.2, POTEM, AL929601.3, RNU6-1239P, AL589182.1, GRAMD4P4, DUXAP9, AL589182.3, AL589743.3, NBEAP5, AL589182.2, OR11H13P, AL589743.2, AL589743.4, CDRT15P13, NBEAP6, AL589743.1, TOMM40P1, DUXAP10, BMS1P17, AL929602.1, LINC01297, GRAMD4P3.
- chr14:68,421,698–68,422,196, 1 gene (within-gene range 0–1): PPIAP6.
- chr14:106,821,174–106,879,812, 10 genes: IGHVII-74-1, IGHV3-75, IGHV3-76, IGHVIII-76-1, MIR5195, IGHV5-78, IGHVII-78-1, IGHV3-79, IGHV7-81, IGHVIII-82.
- chr15:92,819,540–92,899,701, 1 gene (within-gene range 0–2): CHASERR.
- chr19:27,638,483–27,646,483, 2 genes: ERVK-28, AC112702.1.
- chr19:41,506,152–41,521,989, 2 genes: AC243960.2, PLEKHA3P1.
- chr19:42,902,086–42,919,563, 1 gene (within-gene range 0–1): PSG6.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 140 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr14:23,559,565–23,827,396, 10 genes, copy number 5 (within-gene range 1–5): AP1G2, AL135999.1, JPH4, AL135999.3, DHRS2, AL160237.1, BRD7P1, AL160237.3, RN7SKP205, AL160237.2.
- chr16:29,291,220–29,372,110, 1 gene, copy number 5 (within-gene range 2–5): AC025279.1.
- chr16:29,350,746–29,370,272, 1 gene, copy number 5: SNX29P2.
- chr19:37,613,749–37,906,677, 12 genes, copy number 6 (within-gene range 1–6): ZFP30, ZNF781, AC093227.2, SELENOKP1, ZNF607, AC093227.1, AC093227.3, ZNF573, AC016582.2, AC016582.3, AC016582.1, WDR87.
- chr19:39,125,770–40,465,764, 83 genes, copy number 6 (broad region; genes not listed).
- chr19:57,134,096–57,517,559, 33 genes, copy number 5 (within-gene range 1–5): ZIM3, AC025588.2, AC025588.3, DUXA, AC025588.1, ZNF264, AURKC, ZNF805, AC005261.3, ZNF460-AS1, ZNF460, AC005261.5, AC005261.1, AC005261.4, ZNF543, AC005261.2, ZNF304, ZNF547, TRAPPC2B, AC003002.1, ZNF548, AC003002.3, AC003002.2, ZNF17, ZNF749, AC004076.1, AC004076.2, VN1R1, VN1R107P, ZNF772, AC003005.2, ZNF419, AC003005.1.

Autosomal genes at a single copy (total copy number 1): 15,330. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
